Gene-level copy-number profile of tumor specimen TCGA-BC-A3KG-01A from TCGA case TCGA-BC-A3KG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.6 years (25,061 days).
Specimen TCGA-BC-A3KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d6d1a06a-5a67-40dc-9b3e-36aee9f4793d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A3KG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa93d878-208c-4aa2-9038-744091c0a6c5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 31; copy number 2: 10,675; copy number 3: 2,292; copy number 4: 37,282; copy number 5: 4,452; copy number 6: 1,084; copy number 7: 66; copy number 8: 1,282; copy number 9: 1,966; copy number 10: 37; copy number 11: 5; copy number 12: 21; copy number 13: 277; copy number 14: 329; copy number 19: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A3KG-01A-11D-A20V-01): tumor purity 0.95, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:94,938,658–94,990,091, 1 gene (within-gene range 0–2): CYP2C9.
- chr10:95,007,126–95,231,144, 10 genes: CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.1, AL157834.4, AL157834.3, PAWRP1, ACSM6, AL157834.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,638 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–194,198,708, 1,408 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr1:193,756,815–197,478,455, 25 genes, copy number 10 (within-gene range 5–10): RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2, AL353709.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3.
- chr1:198,156,994–203,400,581, 136 genes, copy number 9 (broad region; genes not listed).
- chr1:203,765,177–248,919,946, 1,019 genes, copy number 9–19 (broad region; genes not listed).
- chr2:240,886,048–241,095,568, 7 genes, copy number 9 (within-gene range 4–9): MAB21L4, CROCC2, UICLM, AC104809.1, SNED1, AC093585.1, SNED1-AS1.
- chr5:24,135,160–24,644,978, 6 genes, copy number 9 (within-gene range 5–9): AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10.
- chr5:37,700,331–37,953,827, 4 genes, copy number 10 (within-gene range 5–10): RNU6-484P, GDNF-AS1, GDNF, LINC02117.
- chr6:36,968,141–37,332,970, 10 genes, copy number 12 (within-gene range 8–12): MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2.
- chr6:43,705,949–43,852,333, 7 genes, copy number 10: AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr14:35,388,121–35,469,330, 5 genes, copy number 11: AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4.
- chr19:33,208,664–33,382,686, 11 genes, copy number 12: SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
